TCGA case TCGA-GS-6630 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Hematopoietic and reticuloendothelial systems; Tissue source site: Fundacio Clinic per a la Recerca Biomedica.
https://portal.gdc.cancer.gov/cases/c81277e2-557f-4129-b0ed-84c74e6c8b1e

Biospecimens (2 samples)
- Samples TCGA-GS-6630-10A, TCGA-GS-6630-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
